Somatic mutation profile of tumor specimen CUPP-B38T-TTM1-A (aliquot CUPP-B38T-TTM1-A-1-0-D-A82Z-47) from CCG case CUPP-B38T, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma, endocervical type; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage III; Age at diagnosis: 72.0 years (26,292 days).
Specimen CUPP-B38T-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f91a408-f01c-4977-b762-93435b884d98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CUPP-B38T-NB1-A (Blood Derived Normal), aliquot CUPP-B38T-NB1-A-1-0-D-A82Z-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a088678d-25bd-48f5-9c0b-52e2be187a5b

The open-access MAF lists 217 somatic variants for this specimen: 145 protein-altering or splice-affecting, 59 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 59, Nonsense Mutation 6, Intron 6, In Frame Del 4, Frame Shift Del 3, RNA 3, Splice Region 2, In Frame Ins 2, 5'Flank 2, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASS | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.634); catalogued as rs377076318; called by muse, mutect2, varscan2
- ABCB4 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.01); catalogued as COSV99709878; called by muse, mutect2, varscan2
- ACRV1 | c.89T>C p.I30T | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as rs754410980; called by muse, mutect2, varscan2
- ACSBG2 | c.1328G>T p.G443V | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756393240, COSV53126620; called by muse, mutect2, varscan2
- ACSF3 | c.414C>G p.I138M | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs568882749; called by muse, mutect2
- ACSS1 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1437761545, COSV60222837; called by muse, mutect2, varscan2
- AKAP6 | c.3383G>A p.R1128H | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs369391066; called by muse, mutect2, varscan2
- AKAP9 | c.3425C>T p.A1142V | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as rs1238092488; called by muse, varscan2
- AL035460.1 | c.143T>C p.L48P | Missense Mutation (SNP) | VAF 62/205 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.963); catalogued as rs1162634597; called by muse, mutect2, varscan2
- ANKZF1 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs370759069; called by muse, mutect2, varscan2
- ATG2B | c.4601C>T p.T1534M | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as rs138090571, COSV104379645; called by muse, mutect2, varscan2
- ATP9B | c.1733G>C p.S578T | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as rs531079582; called by muse, mutect2, varscan2
- ATXN10 | c.729A>C p.R243S | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs547165095; called by muse, mutect2, varscan2
- BSPRY | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs376745013; called by muse, mutect2, varscan2
- CACNA1I | c.3031C>G p.R1011G | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs924909056; called by muse, mutect2, varscan2
- CACNA1S | c.2632G>A p.V878M | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs202131129; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC18 | c.1146A>T p.Q382H | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as rs750846073; called by muse, mutect2, varscan2
- CDHR5 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.142); catalogued as rs1221874076; called by muse, mutect2, varscan2
- CENPE | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs150965688; called by muse, varscan2
- CETP | c.541A>G p.K181E | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs1281362325; called by muse, mutect2, varscan2
- COL14A1 | c.2416G>T p.V806F | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV52859190; called by muse, varscan2
- COL5A3 | c.2342_2344del p.A781del | In Frame Del (DEL) | VAF 26/122 reads (21%) | catalogued as rs1200445709; called by mutect2, pindel, varscan2
- COL9A3 | c.1000G>A p.G334R | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs534989733; called by muse, varscan2
- CTNNA3 | c.1823A>T p.D608V | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138314889, COSV101047576; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTU2 | c.1439C>T p.P480L | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200779411; called by muse, mutect2, varscan2
- CYP2A7 | c.328G>C p.V110L | Missense Mutation (SNP) | VAF 55/250 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372343732; called by muse, varscan2
- DCAF1 | c.1076A>G p.Y359C | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782790574; called by muse, mutect2, varscan2
- DHRS12 | c.426_428del p.K142del (on ENST00000444610 / NM_001377930.1; = p.K93del on NM_024705.2 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 18/86 reads (21%) | catalogued as rs750983081; called by mutect2, pindel, varscan2
- DRAXIN | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as rs769135030; called by muse, varscan2
- EEA1 | c.3551C>T p.A1184V | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as rs138526188; called by muse, mutect2, varscan2
- ELANE | c.551G>A p.S184N | Missense Mutation (SNP) | VAF 74/252 reads (29%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1360344559; called by muse, mutect2, varscan2
- FAHD1 | c.698G>C p.S233T | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.153); catalogued as rs781670886; called by muse, mutect2, varscan2
- FAM237A | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs200894319, COSV101405585; called by muse, mutect2, varscan2
- FBXW5 | c.1201A>G p.I401V | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs779146764; called by muse, mutect2, varscan2
- FGF23 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as rs767171941, COSV99426364; called by muse, mutect2, varscan2
- FOXD3 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 54/209 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs184767331; called by muse, varscan2
- GPRIN3 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 44/242 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs752040251; called by muse, mutect2, varscan2
- HELB | c.2377C>T p.P793S | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); catalogued as rs992496895; called by muse, mutect2, varscan2
- HELZ2 | c.5467G>T p.V1823L (on ENST00000467148 / NM_001037335.2; = p.V1254L on NM_033405.3) | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs747031235, COSV71296083; called by muse, mutect2, varscan2
- HERC2 | c.6580G>T p.D2194Y | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.152); catalogued as rs200605180; called by muse, mutect2, varscan2
- HIP1R | c.1757G>A p.R586Q | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs970720668; called by muse, mutect2, varscan2
- HK3 | c.1760_1771del p.C587_D590del | In Frame Del (DEL) | VAF 25/96 reads (26%) | catalogued as rs745603743; called by mutect2, varscan2
- IDE | c.2683G>A p.D895N | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs1051901293; called by muse, mutect2, varscan2
- IL27RA | c.48G>C p.K16N | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.005); catalogued as rs752769222, COSV54602428; called by muse, mutect2, varscan2
- JAML | c.154A>G p.I52V (on ENST00000356289 / NM_001098526.2; = p.I42V on NM_153206.3) | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1446350744; called by muse, mutect2, varscan2
- KASH5 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.986); catalogued as rs772644534; called by muse, mutect2, varscan2
- KIF17 | c.3028A>G p.I1010V | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs758290008; called by muse, mutect2, varscan2
- KIF4B | c.2951T>C p.L984P | Missense Mutation (SNP) | VAF 59/317 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs201982435; called by muse, varscan2
- KLRC2 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as rs1456092861; called by muse, mutect2, varscan2
- KRTAP10-1 | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 158/462 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.228); catalogued as rs62218859; called by muse, varscan2
- KYNU | c.439T>C p.S147P | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.672); catalogued as rs779118861; called by muse, mutect2, varscan2
- LRFN2 | c.715T>G p.F239V | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as rs781621719, COSV100599876; called by muse, mutect2, varscan2
- LTK | c.2507T>G p.L836R | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.289); catalogued as rs941573166; called by muse, mutect2, varscan2
- MRPL14 | c.392A>T p.E131V | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.711); catalogued as rs373870839; called by muse, mutect2, varscan2
- MRPS9 | c.445T>G p.Y149D | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs202077550; called by muse, mutect2, varscan2
- MUC12 | c.4141G>A p.G1381S (on ENST00000379442; = p.G1238S on NM_001164462.1) | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.86); catalogued as rs543329677; called by muse, mutect2, varscan2
- MUC12 | c.4349C>A p.P1450Q (on ENST00000379442; = p.P1307Q on NM_001164462.1) | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.811); catalogued as rs574646218; called by muse, mutect2
- NARS2 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs889193425, COSV99807166; called by muse, mutect2, varscan2
- NAT9 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs201882790; called by muse, mutect2, varscan2
- NBPF10 | c.2065C>A p.P689T | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as rs200946158, COSV61659816; called by muse, varscan2
- NCK2 | c.629C>A p.T210N | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1445013870, COSV51896054; called by muse, mutect2, varscan2
- NCOR2 | c.3106G>A p.A1036T | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.332); catalogued as rs139960265; called by muse, mutect2, varscan2
- NFATC2 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 56/191 reads (29%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.727); catalogued as rs367814095; called by muse, mutect2, varscan2
- NUP37 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs767465099; called by muse, mutect2, varscan2
- OBSCN | c.9279G>A p.E3093= | Splice Region (SNP) | VAF 36/151 reads (24%) | catalogued as rs1404025487, COSV52758781; called by muse, mutect2, varscan2
- OR13J1 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs370940449, COSV65070143; called by muse, mutect2, varscan2
- PAPOLB | c.1898C>T p.T633I | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1350340649; called by muse, mutect2, varscan2
- PHF11 | c.361G>C p.G121R | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as COSV62896475; called by muse, mutect2, varscan2
- PKNOX1 | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.05); catalogued as rs377682317; called by muse, mutect2, varscan2
- PLEKHD1 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs912159633; called by muse, mutect2, varscan2
- PLXND1 | c.112_117dup p.L38_L39dup | In Frame Ins (INS) | VAF 24/75 reads (32%) | catalogued as rs752071943; called by mutect2, varscan2
- PM20D1 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766754304, COSV65649358; called by muse, mutect2
- POLR1A | c.1927A>G p.T643A | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1299919075; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1378del p.L460Wfs*41 | Frame Shift Del (DEL) | VAF 35/138 reads (25%) | catalogued as rs769580536, COSV53453394; called by mutect2, pindel, varscan2
- PRB1 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 66/395 reads (17%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.01); catalogued as rs372368931; called by muse, mutect2, varscan2
- PRDM13 | c.2020C>G p.P674A | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.024); catalogued as rs771065982, COSV65030434; called by muse, mutect2, varscan2
- RABGEF1 | c.811A>G p.N271D (on ENST00000439720 / NM_001287061.2; = p.N258D on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs565375236, COSV53163173; called by muse, mutect2, varscan2
- RBM42 | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs772506401; called by muse, mutect2, varscan2
- RBMXL3 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 66/247 reads (27%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1372688353, COSV57748292; called by muse, varscan2
- RELN | c.1231C>A p.L411I | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs144978163, CM152079, COSV58989985; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPL6 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.721); catalogued as rs369844373; called by muse, mutect2, varscan2
- RPS6KL1 | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as rs199987278; called by muse, mutect2, varscan2
- RSC1A1 | c.379A>G p.T127A | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs1230866845; called by muse, mutect2, varscan2
- SACS | c.7187C>G p.T2396S | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1303289497; called by muse, mutect2, varscan2
- SAFB2 | c.2609C>T p.A870V | Missense Mutation (SNP) | VAF 68/219 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs200296728; called by muse, mutect2, varscan2
- SETD5 | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 40/318 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs944546955, COSV56709540; called by muse, mutect2, varscan2
- SLCO6A1 | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as rs748994119, COSV65805490, COSV65810088; called by muse, mutect2, varscan2
- SOSTDC1 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs748586260, COSV61049413; called by muse, mutect2, varscan2
- SPINT1 | c.834C>A p.F278L | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs753069864, COSV59801227; called by muse, mutect2, varscan2
- SPTBN1 | c.5459G>A p.R1820H | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as rs1317405298; called by muse, mutect2, varscan2
- STK10 | c.2017C>T p.R673* | Nonsense Mutation (SNP) | VAF 34/211 reads (16%) | catalogued as rs774125608, COSV51578643; called by muse, mutect2, varscan2
- TET2 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 64/288 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs773565437, COSV54397097, COSV54406313; called by muse, mutect2, varscan2
- TG | c.4413_4415dup p.E1472dup | In Frame Ins (INS) | VAF 18/112 reads (16%) | catalogued as rs749573523; called by mutect2, pindel, varscan2
- TRAP1 | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.294); catalogued as rs371641134; called by muse, mutect2, varscan2
- TSC2 | c.4355C>T p.S1452L | Missense Mutation (SNP) | VAF 84/276 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as rs45517339; ClinVar: uncertain significance / likely benign / not provided; called by muse, mutect2, varscan2
- TTN | c.79430G>T p.R26477L (on ENST00000591111; = p.R19053L on NM_003319.4) | Missense Mutation (SNP) | VAF 29/154 reads (19%) | PolyPhen probably damaging (0.932); catalogued as rs72648220, COSV100595003; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGT3A2 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as rs770280220; called by muse, mutect2, varscan2
- UPK3BL2 | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 32/448 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs4729825, COSV65025071; called by muse, mutect2
- USP26 | c.472A>G p.M158V | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as rs756473243, COSV63708752; called by muse, mutect2, varscan2
- VARS2 | c.2501G>A p.R834H | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs747564856, COSV58912266; called by muse, mutect2, varscan2
- VCAN | c.8621C>T p.A2874V | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs147798761; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VWA3A | c.3284C>T p.A1095V | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs750392134, COSV55389775, COSV55390999; called by muse, varscan2
- WASHC2C | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs782229472, COSV100313805; called by muse, mutect2, varscan2
- WDPCP | c.159G>A p.A53= | Splice Region (SNP) | VAF 19/96 reads (20%) | catalogued as rs192196713, COSV55431779; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZFAND4 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs369332009; called by muse, varscan2
- ZNF77 | c.17T>A p.F6Y | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375309893; called by muse, mutect2, varscan2
- ACOT4 | c.564_569delinsTCAAAG p.A189_Y190delinsQS | Missense Mutation (ONP) | VAF 27/106 reads (25%) | called by pindel, varscan2*
- ACOX2 | c.1666A>G p.T556A | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BACE1 | c.883C>G p.L295V | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BNIP2 | c.943dup p.*315Lfs*24 | Frame Shift Ins (INS) | VAF 11/107 reads (10%) | called by mutect2, pindel, varscan2
- CBY2 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.443); called by mutect2, varscan2
- CLUH | c.3574_3580del p.E1192Sfs*4 (on ENST00000435359; = p.E1231Sfs*4 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 27/80 reads (34%) | called by mutect2, pindel, varscan2
- DHX29 | c.449T>C p.L150S | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- DHX36 | c.2383C>T p.H795Y | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DOCK5 | c.3693T>A p.Y1231* | Nonsense Mutation (SNP) | VAF 17/101 reads (17%) | called by muse, mutect2, varscan2
- GSE1 | c.99C>A p.C33* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- HSPH1 | c.1262G>A p.S421N | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ITPR2 | c.3361C>G p.L1121V | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- KDM4F | c.217C>T p.Q73* | Nonsense Mutation (SNP) | VAF 58/245 reads (24%) | called by muse, mutect2, varscan2
- LILRA4 | c.1408A>G p.S470G | Missense Mutation (SNP) | VAF 65/317 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- MED11 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- MMP25 | c.1009C>A p.P337T | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- NFATC1 | c.393_395del p.N133del | In Frame Del (DEL) | VAF 49/188 reads (26%) | called by pindel, varscan2
- NOM1 | c.619G>C p.V207L | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NRBP2 | c.1260A>C p.R420S | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- OR1L4 | c.83T>G p.L28R | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR6K2 | c.669_672delinsAGG p.A224Gfs*2 | Frame Shift Del (DEL) | VAF 17/119 reads (14%) | called by pindel, varscan2*
- PCDH9 | c.3424T>A p.C1142S (on ENST00000377865 / NM_203487.3; = p.C1108S on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- PCDHB8 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIGT | c.197A>G p.Y66C | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PIP5K1C | c.1175T>A p.L392Q | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PPM1E | c.1562A>C p.N521T | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by mutect2, varscan2
- PRB1 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0.104); called by muse, varscan2
- PRR36 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 81/274 reads (30%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- RAD18 | c.38T>A p.L13Q | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- STH | c.199T>G p.L67V | Missense Mutation (SNP) | VAF 88/365 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- TMC8 | c.197G>A p.W66* | Nonsense Mutation (SNP) | VAF 50/143 reads (35%) | called by muse, varscan2
- TMTC1 | c.286T>A p.C96S | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TNFAIP6 | c.602A>G p.D201G | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- USP47 | c.1838G>C p.C613S (on ENST00000399455 / NM_001372095.1; = p.C525S on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ZFHX3 | c.49G>C p.G17R | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- ZNF236 | c.4450G>A p.V1484M | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- ZNF621 | c.486T>G p.Y162* | Nonsense Mutation (SNP) | VAF 14/250 reads (6%) | called by muse, mutect2
- ZNF761 | c.47A>C p.E16A | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ZNHIT3 | c.92C>G p.S31W | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ADAMTS10 | c.3114G>T p.S1038= | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as rs1555736450; called by muse, mutect2, varscan2
- ADGRG5 | c.270C>T p.T90= | Silent (SNP) | VAF 31/175 reads (18%) | catalogued as rs764780036; called by muse, mutect2, varscan2
- ADGRL4 | c.1389C>T p.H463= | Silent (SNP) | VAF 41/160 reads (26%) | called by muse, mutect2, varscan2
- ADGRV1 | c.600A>G p.P200= | Silent (SNP) | VAF 30/157 reads (19%) | catalogued as rs776978539; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2A2 | c.2349C>T p.P783= | Silent (SNP) | VAF 31/134 reads (23%) | catalogued as rs372888486; called by muse, mutect2, varscan2
- AUTS2 | c.2319A>G p.S773= | Silent (SNP) | VAF 35/179 reads (20%) | called by muse, mutect2, varscan2
- BAHCC1 | c.5131C>T p.L1711= | Silent (SNP) | VAF 29/149 reads (19%) | catalogued as rs369933422; called by muse, mutect2, varscan2
- BZW2 | c.393T>C p.D131= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as rs552114788; called by mutect2, varscan2
- C11orf96 | c.1035C>T p.P345= (on ENST00000339446; = p.P32= on NM_001145033.2) | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as rs1427314748; called by muse, mutect2, varscan2
- CBFA2T3 | c.960C>T p.T320= | Silent (SNP) | VAF 61/210 reads (29%) | catalogued as rs564040614; called by muse, mutect2, varscan2
- COL6A1 | c.2751C>T p.N917= | Silent (SNP) | VAF 38/173 reads (22%) | catalogued as rs767760988, COSV62611214; ClinVar: likely benign; called by muse, varscan2
- DNAH5 | c.3636C>A p.A1212= | Silent (SNP) | VAF 25/127 reads (20%) | catalogued as rs1319516979; called by muse, mutect2, varscan2
- DPYSL4 | c.831G>A p.E277= | Silent (SNP) | VAF 40/177 reads (23%) | catalogued as rs376130347; called by muse, mutect2, varscan2
- DUSP8 | c.1284G>C p.P428= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs1283397844, COSV59030373; called by muse, mutect2, varscan2
- EIF1AD | c.18G>A p.K6= | Silent (SNP) | VAF 30/150 reads (20%) | catalogued as rs1275557047, COSV56463752; called by muse, mutect2, varscan2
- EIF5A | c.300A>T p.S100= | Silent (SNP) | VAF 27/165 reads (16%) | catalogued as rs1380169177; called by muse, mutect2, varscan2
- EMX2 | c.744G>A p.V248= | Silent (SNP) | VAF 31/205 reads (15%) | catalogued as rs528975205; called by muse, mutect2, varscan2
- FBRSL1 | c.1128C>T p.H376= | Silent (SNP) | VAF 39/153 reads (25%) | catalogued as rs1277537653; called by muse, mutect2, varscan2
- GARNL3 | c.2670A>G p.P890= | Silent (SNP) | VAF 29/181 reads (16%) | catalogued as rs371177003; called by muse, mutect2, varscan2
- GATA3 | c.681C>T p.P227= | Silent (SNP) | VAF 88/317 reads (28%) | catalogued as rs769334413, COSV60520343; called by muse, mutect2, varscan2
- GRM7 | c.2025G>A p.T675= | Silent (SNP) | VAF 28/179 reads (16%) | catalogued as rs267599934; called by muse, mutect2, varscan2
- KDM6B | c.4572G>A p.T1524= | Silent (SNP) | VAF 33/181 reads (18%) | catalogued as rs147988687; called by muse, mutect2, varscan2
- LRP4 | c.141C>T p.A47= | Silent (SNP) | VAF 36/197 reads (18%) | catalogued as rs543418199, COSV66135994; called by muse, mutect2, varscan2
- MBLAC1 | c.555C>T p.G185= | Silent (SNP) | VAF 57/227 reads (25%) | catalogued as rs775384508; called by muse, mutect2, varscan2
- MFSD4A | c.1428G>C p.L476= | Silent (SNP) | VAF 24/176 reads (14%) | catalogued as rs150621373; called by muse, mutect2, varscan2
- MFSD6L | c.714C>A p.S238= | Silent (SNP) | VAF 39/212 reads (18%) | catalogued as COSV61005845; called by muse, mutect2, varscan2
- MOV10L1 | c.720T>G p.L240= | Silent (SNP) | VAF 26/161 reads (16%) | catalogued as rs141847529; called by muse, mutect2, varscan2
- MSX1 | c.846G>C p.A282= | Silent (SNP) | VAF 39/175 reads (22%) | catalogued as rs113829749; called by muse, mutect2, varscan2
- MTA1 | c.177C>T p.A59= | Silent (SNP) | VAF 44/145 reads (30%) | catalogued as rs370694007; called by muse, mutect2, varscan2
- MTRF1 | c.264A>G p.T88= | Silent (SNP) | VAF 33/170 reads (19%) | catalogued as rs943220260; called by muse, mutect2, varscan2
- NFIB | c.321C>T p.S107= | Silent (SNP) | VAF 48/215 reads (22%) | catalogued as rs549868178; called by muse, mutect2, varscan2
- OR5R1 | c.381T>C p.C127= | Silent (SNP) | VAF 54/216 reads (25%) | catalogued as rs1020601583; called by muse, mutect2, varscan2
- OXTR | c.519C>T p.H173= | Silent (SNP) | VAF 42/232 reads (18%) | called by muse, mutect2, varscan2
- PCDHGA1 | c.2025G>A p.L675= | Silent (SNP) | VAF 98/320 reads (31%) | catalogued as rs958838059; called by muse, mutect2, varscan2
- PHYHIP | c.417C>T p.V139= | Silent (SNP) | VAF 16/147 reads (11%) | catalogued as rs372136819; called by muse, mutect2, varscan2
- PLXNA2 | c.4689C>T p.V1563= | Silent (SNP) | VAF 37/158 reads (23%) | catalogued as rs745459207; called by muse, mutect2, varscan2
- PRAG1 | c.1798C>A p.R600= | Silent (SNP) | VAF 51/211 reads (24%) | catalogued as rs528782231, COSV58168652; called by muse, mutect2, varscan2
- PRMT2 | c.297T>C p.D99= | Silent (SNP) | VAF 38/170 reads (22%) | called by muse, mutect2, varscan2
- RALGAPA2 | c.3147C>T p.S1049= | Silent (SNP) | VAF 19/135 reads (14%) | catalogued as rs566841900; called by muse, mutect2, varscan2
- RETREG1 | c.6G>C p.A2= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs750740230; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SCN3A | c.1662C>T p.S554= | Silent (SNP) | VAF 23/148 reads (16%) | catalogued as rs760885665; called by muse, mutect2, varscan2
- SIGLEC11 | c.1140G>A p.P380= | Silent (SNP) | VAF 60/229 reads (26%) | catalogued as rs150811494; called by muse, mutect2, varscan2
- SLC35A4 | c.216C>T p.G72= | Silent (SNP) | VAF 44/163 reads (27%) | catalogued as rs776791523; called by muse, mutect2, varscan2
- SLC5A2 | c.1992C>T p.A664= | Silent (SNP) | VAF 43/135 reads (32%) | catalogued as rs375802106, COSV57894518; called by muse, mutect2, varscan2
- SNRNP200 | c.5439G>C p.L1813= | Silent (SNP) | VAF 47/187 reads (25%) | called by muse, mutect2, varscan2
- SOGA1 | c.1860C>T p.A620= | Silent (SNP) | VAF 47/166 reads (28%) | catalogued as rs772077901; called by muse, mutect2, varscan2
- SRGAP2 | c.1011C>T p.C337= (on ENST00000624873 / NM_001170637.4; = p.C338= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/244 reads (9%) | catalogued as rs782510526; called by muse, varscan2
- STK39 | c.12G>T p.P4= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as rs370635538; called by muse, mutect2, varscan2
- TCF7L1 | c.882T>C p.A294= | Silent (SNP) | VAF 43/195 reads (22%) | catalogued as rs1453443319; called by muse, mutect2, varscan2
- TMEM108 | c.66C>T p.T22= | Silent (SNP) | VAF 36/166 reads (22%) | catalogued as rs182516650, COSV58878378; called by muse, mutect2, varscan2
- TNRC18 | c.1470C>T p.A490= | Silent (SNP) | VAF 48/137 reads (35%) | catalogued as rs762302284, COSV68087682; called by muse, mutect2, varscan2
- TNXB | c.12222G>A p.S4074= (on ENST00000647633; = p.S3827= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 82/306 reads (27%) | catalogued as rs773701143, COSV100926298, COSV64479058; called by muse, mutect2, varscan2
- TRIM71 | c.375C>T p.A125= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as rs760658986; called by muse, mutect2, varscan2
- TSHZ2 | c.2958C>T p.A986= | Silent (SNP) | VAF 29/192 reads (15%) | catalogued as rs376250136; called by muse, mutect2, varscan2
- XKR7 | c.633G>A p.E211= | Silent (SNP) | VAF 33/110 reads (30%) | catalogued as rs1015562470; called by muse, mutect2, varscan2
- ZFC3H1 | c.2613T>C p.L871= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as rs1388502556; called by muse, mutect2, varscan2
- ZNF775 | c.219G>A p.R73= | Silent (SNP) | VAF 73/228 reads (32%) | catalogued as rs1354911842; called by muse, mutect2, varscan2
- ZNF782 | c.1995G>A p.Q665= | Silent (SNP) | VAF 45/184 reads (24%) | called by muse, mutect2, varscan2
- ZNRF3 | c.1452G>T p.G484= (on ENST00000544604 / NM_001206998.2; = p.G384= on NM_032173.3) | Silent (SNP) | VAF 47/196 reads (24%) | called by muse, mutect2, varscan2
- ACAD8 | c.1195+202G>T | Intron (SNP) | VAF 42/208 reads (20%) | catalogued as rs1321345386; called by muse, mutect2, varscan2
- AL672310.1 | n.115A>C | RNA (SNP) | VAF 33/310 reads (11%) | catalogued as rs9767616; called by muse, varscan2
- C4orf50 | chr4:5990245 C>T | 5'Flank (SNP) | VAF 40/214 reads (19%) | catalogued as rs1223062620; called by muse, mutect2, varscan2
- CALU | c.415+215C>T | Intron (SNP) | VAF 25/134 reads (19%) | catalogued as rs563892606; called by muse, mutect2, varscan2
- CCNI2 | c.775-36G>A | Intron (SNP) | VAF 25/148 reads (17%) | catalogued as rs560757045, COSV51523740; called by muse, mutect2, varscan2
- DUXAP10 | n.2725C>T | RNA (SNP) | VAF 32/215 reads (15%) | catalogued as rs774153242; called by muse, mutect2, varscan2
- GOLGA6L3 | n.1017G>A | RNA (SNP) | VAF 30/440 reads (7%) | catalogued as rs202117168; called by muse, mutect2, varscan2
- KCNH7 | chr2:162371375 G>C | 3'Flank (SNP) | VAF 18/106 reads (17%) | called by muse, mutect2, varscan2
- LNPEP | chr5:96936008 C>T | 5'Flank (SNP) | VAF 52/174 reads (30%) | called by muse, mutect2, varscan2
- MFSD4B | c.*266C>T | 3'UTR (SNP) | VAF 35/149 reads (23%) | catalogued as rs758795099, COSV64349274; called by muse, mutect2, varscan2
- OSBP2 | c.854-47738C>A | Intron (SNP) | VAF 35/148 reads (24%) | catalogued as rs540369275; called by muse, mutect2, varscan2
- ROBO2 | c.3935-1767G>A | Intron (SNP) | VAF 18/121 reads (15%) | catalogued as rs181394187; called by muse, mutect2, varscan2
- TXNRD1 | c.415-1300C>G | Intron (SNP) | VAF 27/154 reads (18%) | catalogued as rs1404420369; called by muse, mutect2, varscan2
